Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00D, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00D-01A (Primary Tumor).

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: ascending colon: C18.2 *hw* 3/28/11

Sample ID #:

Diagnosis / Diagnoses:

Right hemicolectomy specimen with multiple tubular colonic mucosal adenomas with moderate dysplasia (synonym: low-grade intra-epithelial neoplasia) and under inclusion of an ulcerated, moderately differentiated adenocarcinoma in the ascending colon, with infiltration of the lamina muscularis propria and without regional lymph node metastases (G2, pT2 pN0 0/28 L0 V0 R0).

HIFAA Discrepancy		
Reviewed Initial		

km *hw* *5/16/11*

Source: NCI Genomic Data Commons file a8ae2fce-9937-4229-89de-ff958c20b09b (TCGA-AA-A00D.0D0B2106-A2F1-4D5B-96CD-8E46D3A9D60B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).